Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A169, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A169-01A (Primary Tumor).

[page 1 of 3]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology Site Code: Endometrium
C54.1

TISSUE DESCRIPTION:

A1 J1 K1 L1 M1 M2 N1 O1 P1 P2 P3 Q1 Q2 R1 S1 B1
C1 C2 C3
C4 C5 C6 C7 C8 C9 C10 D1 D2 D3 D4 D5 D6 D7 D8 D9 D10 D11
E1 E2 E3 E4
E5 E6 E7 E8 E9 E10 E11 E12 F1 F2 G1 H1 I1
Uterus, right ovary (3.0 x 1.1 x 1.0 cm) with 9.0 cm
segment of
right fallopian tube, and 4.2 cm segment of left fallopian
tube
together weighing 120.0 grams; tissue from the bladder
peritoneum
(2.0 x 0.6 x 0.3 cm); tissue from the left bladder
peritoneum (0.8 x
0.5 x 0.3 cm); right and left pelvic lymph nodes; portion
of omentum
(30.0 x 18.0 x 3.0 cm); separately submitted specimens
from the
right colic gutter [No. 1 (0.6 x 0.4 x 0.2 cm), No. 2 (0.3
x 0.3 x
0.3 cm)], separately submitted specimens from the right
diaphragm
[No. 1 (0.3 x 0.3 x 0.2 cm), No. 2 (0.3 x 0.3 x 0.2 cm)];
right
gonadal vessels (8.2 cm in length); right para-aortic
lymph nodes
above and below the inferior mesenteric artery; tissue
from the left
colic gutter (1.5 x .11 x 0.4 cm); left gonadal vessels
(9.0 cm in
length); left para-aortic lymph nodes above and below the
inferior
mesenteric artery; and tissue from the small bowel
mesentery (0.2 x
0.1 x 0.1 cm).

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade II (of III) endometrial
adenocarcinoma, endometrioid type, forming a polypoid mass
(6.0 x
5.1 x 1.2 cm) involving the entire uterine cavity and
extending to

[page 2 of 3]
the lower uterine cavity. The tumor invades 0.5 cm into the myometrium (total myometrial thickness, 1.1 cm). A single intramural leiomyoma (0.2 cm in greatest dimension) is also identified. The endocervical canal and ectocervix are negative for tumor. The right ovary and bilateral fallopian tubes show no diagnostic abnormalities.

Peritoneum, bladder, biopsy: Positive for metastatic adenocarcinoma, consistent with endometrial primary.

Peritoneum, left bladder, biopsy: Negative for tumor.

Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (4 external iliac, 2 common iliac, 3 obturator) are negative for tumor. Specimen submitted as "right internal iliac lymph nodes" did not contain nodal tissue .

Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (5 external iliac, 1 internal iliac, 4 common iliac, 10 obturator) are negative for tumor .

Omentum, omentectomy: Fibroadipose tissue, negative for tumor .

Soft tissue, right colic gutter Nos. 1 and 2, biopsies: Fibroadipose tissue, negative for tumor, both specimens .

Soft tissue, right diaphragm Nos. 1 and 2, biopsies: Fibroconnective tissue, negative for tumor, both specimens (.

Lymph nodes, left and right para-aortic above and below the inferior mesenteric artery, excision: Multiple para-aortic lymph nodes above

[page 3 of 3]
the inferior mesenteric artery (7 left, 4 right) are negative for tumor. Multiple para-aortic lymph nodes below the inferior mesenteric artery (7 left, 5 right) are negative for tumor

Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor

Soft tissue, left colic gutter, biopsy: Fibroadipose tissue, negative for tumor

Small bowel, mesentery, biopsy: Negative for tumor (

Small bowel, serosa, biopsy: Positive for metastatic adenocarcinoma consistent with endometrial primary

Immunohistochemical studies for mismatch repair will be reported in an addendum.

ADDENDUM:

Immunoperoxidase stains were performed on paraffin-embedded tumor sections (block C10). The neoplasm epithelial cells show intact expression of DNA mismatch repair enzymes hMLH1, hMSH2, hMSH6 and hPMS2. These findings do not suggest defective DNA mismatch repair.

Source: NCI Genomic Data Commons file d3ba98e8-74fc-4035-bc0d-bc9058b1b8b2 (TCGA-D1-A169.F7B4C0DC-2259-4A0A-81D3-E145EFA91279.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).